Somatic mutation profile of tumor specimen TCGA-AO-A0J7-01A (aliquot TCGA-AO-A0J7-01A-11W-A050-09) from TCGA case TCGA-AO-A0J7, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.0 years (26,281 days).
Specimen TCGA-AO-A0J7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c378a90-f175-4d9a-8e4b-d9f1214f1474.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0J7-10A (Blood Derived Normal), aliquot TCGA-AO-A0J7-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02bf8475-81ee-4edd-bd15-cbe9acfcfb2c

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 2, Frame Shift Ins 2, 3'Flank 1, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 44/107 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALOX5 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV65554676; called by muse, mutect2, varscan2
- BEND2 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 24/351 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV66217074; called by muse, mutect2
- CACNA2D2 | c.2857G>A p.G953S (on ENST00000479441 / NM_001174051.3; = p.G946S on NM_006030.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.619); catalogued as COSV99816670; called by muse, mutect2
- G6PC2 | c.84T>A p.F28L | Missense Mutation (SNP) | VAF 129/245 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0.092); catalogued as COSV56373637; called by muse, mutect2, varscan2
- INTS10 | c.442-1G>A p.X148_splice | Splice Site (SNP) | VAF 40/116 reads (34%) | catalogued as COSV67605067; called by muse, mutect2, varscan2
- KCNH7 | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59814703; called by muse, mutect2, varscan2
- KRT79 | c.1486dup p.A496Gfs*13 | Frame Shift Ins (INS) | VAF 10/65 reads (15%) | catalogued as rs746321620; called by mutect2, varscan2
- PCNX2 | c.5552G>A p.G1851E | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs1477313184, COSV50906159; called by muse, mutect2, varscan2
- PLXNA1 | c.5656G>A p.E1886K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV52532981; called by muse, mutect2, varscan2
- TRMT2B | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 101/230 reads (44%) | catalogued as COSV58621256; called by muse, mutect2, varscan2
- VSIG8 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.975); catalogued as rs141528275, COSV100928743; called by muse, mutect2, varscan2
- MAP3K1 | c.3611_3612del p.I1204Sfs*7 | Frame Shift Del (DEL) | VAF 45/119 reads (38%) | called by mutect2, pindel, varscan2
- PGR | c.1786dup p.E596Gfs*13 | Frame Shift Ins (INS) | VAF 18/27 reads (67%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.3735C>T p.S1245= (on ENST00000651564; = p.S1198= on NM_015692.5) | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs768021515, COSV71597429; called by muse, mutect2, varscan2
- PGBD2 | c.123G>A p.E41= | Silent (SNP) | VAF 59/175 reads (34%) | catalogued as rs1159556933, COSV61401207; called by muse, mutect2, varscan2
- S1PR3 | c.645C>T p.Y215= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as rs373129056; called by muse, mutect2, varscan2
- STOX1 | c.576C>T p.Y192= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV53818203; called by muse, mutect2, varscan2
- FAM183BP | n.1028G>A | RNA (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- MYL3 | chr3:46831974 A>G | 3'Flank (SNP) | VAF 38/79 reads (48%) | catalogued as rs770762268, COSV70134156; called by muse, mutect2, varscan2
